Somatic mutation profile of tumor specimen TCGA-D8-A146-01A (aliquot TCGA-D8-A146-01A-31D-A10Y-09) from TCGA case TCGA-D8-A146, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.1 years (20,861 days).
Specimen TCGA-D8-A146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 286b9b00-6348-495c-944d-91afcf5b4f6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A146-10A (Blood Derived Normal), aliquot TCGA-D8-A146-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d17f87-5a10-4c06-b546-457a14d7aab9

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 95/279 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTG1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV59511701; called by muse, mutect2, varscan2
- CELF1 | c.894G>T p.G298= (on ENST00000358597 / NM_001376422.1; = p.G294= on NM_006560.4 and 10 other RefSeq transcripts) | Splice Region (SNP) | VAF 18/149 reads (12%) | catalogued as COSV60114635; called by muse, mutect2, varscan2
- CMTR1 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65091474; called by muse, mutect2, varscan2
- COG3 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1158123601, COSV63074549; called by muse, mutect2, varscan2
- DNAH3 | c.7733G>A p.R2578Q | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs541798583, COSV54543282; called by muse, mutect2, varscan2
- DSP | c.3956C>T p.T1319I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs138599871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EOLA2 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV62207515; called by muse, mutect2, varscan2
- LRRTM3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV63666111; called by muse, mutect2, varscan2
- MAMLD1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.288); catalogued as COSV53379381; called by muse, mutect2, varscan2
- METTL5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 68/582 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV53627528; called by muse, mutect2, varscan2
- MICU3 | c.426del p.T143Hfs*13 | Frame Shift Del (DEL) | VAF 105/434 reads (24%) | catalogued as COSV58849463; called by mutect2, pindel, varscan2
- NEXMIF | c.3280A>G p.T1094A | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1301181138, COSV50076171; called by muse, mutect2, varscan2
- NPTXR | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60729268; called by muse, mutect2, varscan2
- PITPNM1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256171202, COSV62709449; called by muse, mutect2, varscan2
- PPFIA3 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs968525088, COSV61953991; called by muse, mutect2, varscan2
- SCRN3 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 90/308 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs542985134, COSV55807135; called by muse, mutect2, varscan2
- SFXN4 | c.497T>G p.L166* | Nonsense Mutation (SNP) | VAF 67/293 reads (23%) | catalogued as COSV57460819; called by muse, mutect2, varscan2
- SLC12A5 | c.2312C>T p.S771F (on ENST00000454036 / NM_001134771.2; = p.S748F on NM_020708.5) | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV54799480; called by muse, mutect2, varscan2
- SLC5A6 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60160871; called by muse, mutect2, varscan2
- SOX30 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 58/325 reads (18%) | catalogued as COSV53936571; called by muse, mutect2, varscan2
- SPICE1 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99871272; called by muse, mutect2
- TMCO1 | c.442T>A p.C148S (on ENST00000612311 / NM_001256164.1; = p.C97S on NM_019026.6) | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100903138; called by muse, mutect2
- UGT1A6 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV59395863; called by muse, mutect2, varscan2
- ZNF587 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779562247, COSV57150302; called by muse, mutect2, varscan2
- ZNFX1 | c.5703G>A p.W1901* | Nonsense Mutation (SNP) | VAF 114/294 reads (39%) | catalogued as COSV65600751; called by muse, mutect2, varscan2
- DDX11 | c.465dup p.A156Cfs*30 | Frame Shift Ins (INS) | VAF 14/142 reads (10%) | called by mutect2, pindel
- RBBP8 | c.1544_1571del p.K515Ifs*2 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel
- SMS | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- CYBC1 | c.480C>T p.F160= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV60065435; called by muse, mutect2, varscan2
- ITIH4 | c.225G>A p.K75= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV56572515, COSV56577450; called by muse, mutect2, varscan2
- TNN | c.1923C>T p.D641= | Silent (SNP) | VAF 71/321 reads (22%) | catalogued as COSV99511818, COSV99512666; called by muse, mutect2, varscan2
- TSSK3 | c.78A>G p.E26= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV100344674; called by muse, mutect2
- USP15 | c.2337A>G p.K779= (on ENST00000280377 / NM_001351159.2; = p.K750= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs1490475781, COSV54796885; called by muse, mutect2, varscan2
- ZNF181 | c.1326C>T p.F442= | Silent (SNP) | VAF 51/231 reads (22%) | catalogued as COSV67627187; called by muse, mutect2, varscan2
